TCGA case TCGA-EJ-5504 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e1c3d1bd-cf8f-4fa4-ac8e-bf9e54f7aad4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 65.9 years (24,072 days); Year of diagnosis: 2010; Method of diagnosis: Core Biopsy; AJCC clinical T: T2c; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N1; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason grade tertiary: Pattern 5; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 18; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Overlapping/multiple zones.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (8 entries)
- Day 25 (initial diagnosis): Days to imaging: 25 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 25 (initial diagnosis): Days to imaging: 25 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: Extraprostatic Extension, Regional Lymphadenopathy.
- Days to follow up: 77 days; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 77 days.
- Days to follow up: 229 days; Disease response: With Tumor.
- Days to follow up: 736 days (2.0 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 736 days (2.0 years).
- Days to follow up: 880 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 1,427 days (3.9 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Timepoint: Post Initial Treatment.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 1 ng/mL (day 77).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EJ-5504-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-EJ-5504-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-EJ-5504-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EJ-5504-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EJ-5504-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Biochemical recurrence indicator: Yes.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Diagnostic ct abd pelvis results: Ct scan ab pelvis results: Extraprostatic Extension (regional lymphadenopathy)[e.g. cN1].
- Stage record, Psa: PSA most recent results: 1.0.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 3; Gleason pattern tertiary: 5.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,427 days; disease-specific survival: no event (censored), 1,427 days; progression-free interval: no event (censored), 1,427 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EJ-5504-01A-01D-1574-01): tumor purity 0.35, ploidy 1.86, whole-genome doublings 0.
